Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YU, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YU-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

ICD 6-3
Fibromyosarcoma 8811/3
Site @ Chest wall NOS
C49.3
JED 8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with right chest wall high grade sarcoma.

Specimens Submitted:

- 1: Sarcoma, right chest wall
- 2: Skin angioma right chest

DIAGNOSIS:

1. Soft tissue, right chest wall; radical resection:
- Myxofibrosarcoma, high grade, involving fibroadipose tissue and skeletal muscle, see note.
- The tumor measures 5.5 x 4.7 x 3.0 cm.
- Approximately 5% of the tumor is necrotic.
- Approximately 90% of the tumor is myxoid.
- The surgical margins are free of tumor.

Note: No glandular breast parenchyma is identified. The prior biopsy has been reviewed.

2. Skin, right chest; excision:
- Hemangioma, completely excised.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out - *

Gross Description:

1. The specimen is received fresh, labeled "right chest wall", and consists of a piece of fibrofatty tissue and skeletal muscle that measures 11 x 7.0 x 6.5 cm. The specimen has been oriented by the surgeon with a short stitch designating the superior margin and long stitch designating the lateral margin. The specimen is inked as follows: superior -black, inferior-orange,

** Continued on next page **

[page 2 of 3]
----- Page 2 of 3
medial -red, lateral-green, anterior-blue, posterior -yellow. The specimen is serially sectioned to reveal a well-circumscribed mass that measures 5.5 x 4.7 x 3.0 cm and displays tan-yellow, heterogenous cut surfaces. The mass is located 0.4 cm from superior and anterior margins, 0.7 cm from the inferior margin, 1.0 cm from the lateral margin and more than 1.0 cm from all other margins. Representative sections are submitted. Tissue is submitted for TPS. Gross photographs are taken.

Summary of sections:

SM- superior margin
IM-inferior margin
MM-medial margin
LM-lateral margin
AM-anterior margin
PM posterior margin
T-tumor

2. The specimen is received in formalin, labeled "Skin angioma right chest" and consists of an unoriented ellipse of white tan skin that measures 1.3 x 0.4 x 0.3 cm. Roughly at the center of the skin surface, a nodule is identified that measures 0.2 x 0.2 cm and is located less than 0.1 cm from the nearest margin. The margins are inked black. The specimen is serially sectioned from tip to tip and entirely submitted.

Summary of sections:

T1 - tip one
SS - serial sections
T2 - tip two

Summary of Sections:

Part 1: Sarcoma, right chest wall

Block	Sect.	Site	PCs
2		AM	2
2		IM	2
2		LM	2
2		MM	2
2		PM	2
2		SM	2
7		T	7

Part 2: Skin angioma right chest

Block	Sect.	Site	PCs
4		SS	4
1		T1	1
1		T2	1

** Continued on next page **

[page 3 of 3]
[REDACTED]

[REDACTED]

** End of Report **

Rad tx to brain
w 7/23/13

BCR

Dual, Synchronous Primary	☒	

Source: NCI Genomic Data Commons file ee143b63-1e90-4e3e-9f64-7ce83f7478e7 (TCGA-DX-A6YU.C3974496-AD92-4C14-B8C0-7BF2AA0BA37D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).